CCDI case PBCDAS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/1e16fd39-8ec5-4936-aff5-e38498405d41

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ependymoma, anaplastic: ICD-O-3 morphology code: 9392/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 1.5 years (533 days).

Biospecimens (3 samples)
- Sample 0DP6HJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DP6I4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DP6I9: Tissue type: Tumor; Specimen type: Solid Tissue.
